Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GW, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GW-01A (Primary Tumor).

Surgical Pathology

CASE NUMBER:

DIAGNOSIS: Adrenal, right, mass (excision): Pheochromocytoma.

Final

Final Results

CLINICAL INFORMATION: Brief Clinical History: pheo Specimen Taken For
Protocol: Yes
Allocate Order to Protocol:

PROCEDURE: Operative Findings: hypervascular right adrenal mass
Post-Operative
Diagnosis: pheo Pre-Operative Diagnosis: pheo

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION: "Right adrenal gland". Received fresh from the O.R. is a soft tan well-circumscribed nodule measuring 7 x 5 x 4 cm, and weighing 68.84 grams. It is inked in blue, trisected revealing tan soft homogeneous cut surface with no apparent hemorrhage. Approximately 60% of tissue not involving the inked margin is procured for Dr. Laboratory. The remaining tissue is sent to Surgical Pathology. Pictures are taken. Procurement is carried out by Dr.

The specimen received at the Laboratory of Pathology is consistent with the above description. Representative sections of tumor are submitted in white cassettes labeled A-C for permanent processing. Sections of tumor with relations to adrenal gland are submitted in white cassettes labeled D-F for permanent processing.

Gross description dictated by

No consultants

#

#

Requested By:

Do not file in Medical Record

Criteria	W 5/23/13	Yes	No

Source: NCI Genomic Data Commons file da6cd9da-5093-44de-8965-663273af348f (TCGA-QR-A6GW.AF391D3F-D978-474C-8E0C-90FC7EEF4701.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).